Surgical pathology report (de-identified scan), TCGA case TCGA-CZ-4857, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Harvard, specimen TCGA-CZ-4857-01A (Primary Tumor).

[page 1 of 3]
Accession Number: [REDACTED] Report Status
Type: Surgical Pathology
Specimen Type: Kidney, partial or total resection
Procedure Date: [REDACTED]
Ordering Provider: [REDACTED]

CASE: [REDACTED]
PATIENT: [REDACTED]

Resident: [REDACTED]
Pathologist: [REDACTED]

TCGA-CZ-4857

PATHOLOGIC DIAGNOSIS:

RIGHT KIDNEY, NEPHRECTOMY:

RENAL CELL CARCINOMA, CLEAR CELL TYPE (9.2 cm), Furman grade 3 of 4.
Tumor does not invade Gerota's fascia.
Tumor extends into the wall but not through the renal vein.
Vascular and ureteral margins negative for tumor.
No lymphovascular invasion is identified.
Two (2) lymph nodes; no tumor present.

REGIONAL LYMPH NODES, BIOPSY:

One (1) lymph node; no tumor present.

CLINICAL DATA:

History: [REDACTED] with pain and hematuria. R kidney mass and possible lung nodules.

Operation: Nephrectomy

Clinical Diagnosis: As above

TISSUE SUBMITTED:

- #1) R. kidney
- #2) Regional lymph nodes

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, labeled "#1. R. kidney", consists of a right radical nephrectomy specimen (976.5 grams, 28.6 x 10.8 x 6.7 cm), to include right kidney (16.3 x 8.0 x 5.5 cm), ureter (8.0 cm in length x 0.4 cm in diameter), renal vein at hilum (0.5 cm in length x 1.2 cm in diameter), renal artery (3.5 cm in length x 0.4 cm in diameter), additional clip vascular structure (11 cm in length x 0.3 cm in diameter - consistent with a vein), Gerota's fascia (12.5 x 7.0 x 0.1 cm) and abundant attached perinephric fat. There is a golden yellow/red/tan, partially encapsulated nodular focally hemorrhagic centrally necrotic mass (9.2 x 7.7 x 5.7 cm) within the upper pole, focally impinging upon the renal capsule and closely opposed black-inked Gerota's fascia, focally appears to impinge the renal vein, coming to within 1.2 cm of the renal vein, 2.8 cm from the renal artery margin, and grossly appears to abut but invade the renal pelvis coming to within 8 cm of the ureteral margin. Representative sections of the tumor are submitted to cytogenetics and electron microscopy for future studies. A 0.4 x 0.3 x 0.3 cm white firm nodule is identified within a medullary pyramid along the anterior/lateral aspect of within the mid pole of the kidney, 1.1 cm lateral and inferior to the aforementioned mass. The remaining renal parenchyma displays a well-defined cortico-medullary junction with no other gross lesions. Two brown/pink rubbery nodules (1.3 cm and 1.5 cm in greatest dimension) are identified within the perihilar soft tissue. Representative cortex is submitted for future electron microscopy, immunofluorescence studies and to the tissue bank for special studies. Tumor is also submitted to the tissue bank (T1, T2 and T3).

Micro A1: ureteral, arterial and venous margins, en face, 4 frags, [REDACTED]
Micro A2: "T1", 1 frag, [REDACTED]
Micro A3: "T2", 1 frag, [REDACTED]
Micro A4: "T3", 1 frag, [REDACTED]
Micro A5-6: renal mass at deepest extension, in relationship to Gerota's fascia, 2 frags, [REDACTED]

[page 2 of 3]
Pathology Report

Micro A7-8: renal mass at possible invasion into vein and relationship with
pelvis, 2 frags, [REDACTED]

Micro A9: random tumor, 1 frag, [REDACTED]

Micro A10-11: additional white firm nodule in relationship to mass, 2 frags,
[REDACTED]

Micro A12: cortico-medullary junction, 1 frag, [REDACTED]

Micro A13: bisected nodules (? lymph node), 2 frags, [REDACTED]

Micro A14: bisected perihilar nodule (? lymph node), 2 frags, [REDACTED]

Part B, labeled "#2. regional nodes", consists of an unoriented portion of
yellow/tan fatty soft tissue (6.5 x 4.2 x 2.0 cm). Sectioning reveals a large
gray/pink/yellow matted firm probable lymph node (5.4 x 3.3 x 2.0 cm). The
tissue is bisected and one-half of the entire matted lymph node is submitted.

Micro B1-6: large matted lymph node (one-half of specimen), 6 frags, [REDACTED]

[REDACTED]

By his/her signature below, the senior physician certifies that he/she
personally conducted a microscopic examination ("gross only" exam if so stated)
of the described specimen(s) and rendered or confirmed the diagnosis(es)
related thereto.

Resident Review by [REDACTED]
Final Diagnosis by [REDACTED]

[page 3 of 3]
Accession Number: [REDACTED]
Type: Cytogenetics
CASE: [REDACTED]
PATIENT: [REDACTED]
Cytogeneticist
[REDACTED]

Report Status: [REDACTED]

KARYOTYPE: T1: 92,XXYY,der(1)x2,del(3)(p12)x2[1] T3: 46,XY

METAPHASES COUNTED: 16 ANALYZED: 6 SCORED: 10 BANDING: GTG

INTERPRETATION:

Three different specimens from the same tumor were received.

Specimen #1: only 1 metaphase cell was obtained, and contains a deletion of the short arm of chromosome 3, a characteristic finding in renal cell carcinoma, clear cell type.

Specimen #2: No metaphases were obtained, and therefore the cytogenetic analysis could not be performed.

Specimen #3: No cytogenetic aberrations were identified.

COMMENTS:

Mosaicism and small chromosome anomalies may not be detectable using the standard methods employed. Chromosome analysis was performed at a level of 400 bands or greater.

INDICATION FOR TEST:

? RCC

[REDACTED]

Source: NCI Genomic Data Commons file e1f1a5c8-cfda-471d-a535-3ce2c50b0f10 (TCGA-CZ-4857.FC5D937E-280D-47EE-A6CE-4EB7B1B6430F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).